CPTAC case C3L-00622 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5f7accb9-d655-45fb-bae0-d8cd02c11285

Demographics
Sex at birth: male; Race: white; Year of birth: 1944; Vital status: Dead; Days to death: 1,041 days (2.9 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: Canada.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 72.9 years (26,616 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Residual disease: R1; Last known disease status: With tumor; Days to last known disease status: 1,041 days (2.9 years); Progression or recurrence: yes; Days to last follow up: 1,041 days (2.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 22; Lymphatic invasion present: Yes; Margin status: Involved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 290 days; Disease response: Progressive Disease; Karnofsky performance status: 50; ECOG performance status: 3.
- Days to follow up: 1,041 days (2.9 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 172 days; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 86.5 kg; Height: 173.5 cm; BMI: 28.74; Comorbidities: Hypothyroidism.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Tobacco smoking quit year: 1988; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (6 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00622-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 106 mg; Time between excision and freezing: 47 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00622-21: Section location: Head; Percent tumor nuclei: 40; Percent necrosis: 0.
- Sample C3L-00622-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 0.099 mg.
- Sample C3L-00622-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 52 mg; Time between excision and freezing: 47 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00622-23: Section location: Head; Percent tumor nuclei: 40; Percent necrosis: 0.
- Sample C3L-00622-04: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 101 mg; Time between excision and freezing: 49 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00622-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -6 days; Method of sample procurement: Blood Draw.
- Sample C3L-00622-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
